Somatic mutation profile of tumor specimen MP2PRT-PAURHS-TMP1-A (aliquot MP2PRT-PAURHS-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAURHS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,793 days).
Specimen MP2PRT-PAURHS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 432ba57a-b58a-47d3-90a9-72afe6b954e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAURHS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAURHS-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3971e15a-e3c6-4954-b907-7f1c9837f4af

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMTN | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 241/549 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs145460473; called by muse, mutect2, varscan2
- H2BW1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 51/526 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs367978385, COSV99475079; called by muse, mutect2, varscan2
- SETD1B | c.22dup p.H8Pfs*30 | Frame Shift Ins (INS) | VAF 114/368 reads (31%) | catalogued as rs777278685; called by mutect2, varscan2
- TMEM132C | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 13/462 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.315); catalogued as rs1304461693; called by muse, mutect2
- TMEM151A | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 135/812 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as rs780842555, COSV59174867; called by muse, mutect2, varscan2
- ATRX | c.6458G>A p.R2153H | Missense Mutation (SNP) | VAF 141/336 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLL4 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 207/497 reads (42%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.349del p.R117del | Frame Shift Del (DEL) | VAF 26/125 reads (21%) | called by mutect2, varscan2
- MYH7 | c.5488C>A p.Q1830K | Missense Mutation (SNP) | VAF 262/637 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C16orf89 | c.126G>A p.A42= | Silent (SNP) | VAF 206/518 reads (40%) | catalogued as rs187308197; called by muse, mutect2, varscan2
- COL7A1 | c.345C>A p.G115= | Silent (SNP) | VAF 52/730 reads (7%) | called by muse, mutect2
- PCDH7 | c.3060C>T p.A1020= | Silent (SNP) | VAF 188/450 reads (42%) | catalogued as rs200262066; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-2781C>T | Intron (SNP) | VAF 134/297 reads (45%) | called by muse, mutect2, varscan2
- PPP1R14C | c.*684T>A | 3'UTR (SNP) | VAF 160/416 reads (38%) | called by muse, mutect2, varscan2
